CPTAC case C3L-04844 — Tonsil — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a2a4f11-e9bb-4291-9089-24b5e77d285b

Demographics
Sex at birth: female; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Tonsil, NOS; Age at diagnosis: 61.0 years (22,268 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,857 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,857 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 79; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 290 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 824 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 1,096 days (3.0 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 702 days (1.9 years); Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,096 days (3.0 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,415 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 1,857 days (5.1 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 0.

Other clinical attributes
- Weight: 57.8 kg; Height: 167 cm; BMI: 20.73.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 50; Cigarettes per day: 25; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 44.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04844-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tonsil; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 39 days; Initial weight: 123 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04844-21: Section location: Tonsil; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-04844-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 39 days; Method of sample procurement: Blood Draw.
